Somatic mutation profile of tumor specimen 0DVR7W from CCDI case PBCNAN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,368 days).
Specimen 0DVR7W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7f84aa0-19a6-4072-bca1-88d3768ccda1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVR5U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fa0b043-8990-4c6a-9afd-ea56e0abfc82

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 9, Nonsense Mutation 2, Splice Site 2, Intron 2, 3'UTR 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMBT1 | c.1415G>A p.S472N | Missense Mutation (SNP) | VAF 106/498 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1219900398; called by muse, mutect2
- DNAH9 | c.10348G>A p.V3450M | Missense Mutation (SNP) | VAF 185/214 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs775744600, COSV52340086; called by muse, mutect2, varscan2
- FAM117A | c.818T>C p.M273T | Missense Mutation (SNP) | VAF 67/490 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs1036546692; called by muse, mutect2, varscan2
- FTMT | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.551); catalogued as COSV100360355; called by muse, mutect2, varscan2
- MACF1 | c.13654G>T p.E4552* (on ENST00000372915; = p.E2485* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 108/575 reads (19%) | catalogued as COSV99243483; called by muse, mutect2, varscan2
- MYO15A | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 90/104 reads (87%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.586); catalogued as rs766426746, COSV52764152; called by muse, mutect2, varscan2
- NPIPB2 | c.1064G>A p.R355Q (on ENST00000399147; = p.R215Q on NM_001355514.1) | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.859); catalogued as rs1361966986; called by muse, mutect2, varscan2
- PLOD3 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs779199558; called by muse, mutect2, varscan2
- SASH3 | c.153+1G>T p.X51_splice | Splice Site (SNP) | VAF 86/212 reads (41%) | catalogued as COSV63556147; called by mutect2, varscan2
- AKAP3 | c.26A>G p.Q9R | Missense Mutation (SNP) | VAF 23/553 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- CASP7 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 104/595 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLSTN2 | c.1637A>G p.D546G | Missense Mutation (SNP) | VAF 22/554 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH11 | c.1843A>G p.K615E | Missense Mutation (SNP) | VAF 22/872 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2
- DNAH3 | c.8126T>A p.L2709H | Missense Mutation (SNP) | VAF 162/855 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL2RA | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 114/371 reads (31%) | called by muse, mutect2, varscan2
- MROH2A | c.2708T>G p.I903R | Missense Mutation (SNP) | VAF 105/859 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- NKRF | c.1931G>A p.G644D | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PCDHGB3 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 97/394 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRR14L | c.1906T>C p.S636P | Missense Mutation (SNP) | VAF 167/930 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC30A5 | c.783+2T>C p.X261_splice | Splice Site (SNP) | VAF 219/872 reads (25%) | called by muse, mutect2, varscan2
- TIMP2 | c.184del p.Y62Mfs*15 | Frame Shift Del (DEL) | VAF 102/954 reads (11%) | called by mutect2, varscan2
- CROCC | c.1758C>T p.D586= | Silent (SNP) | VAF 22/713 reads (3%) | called by muse, mutect2
- FBXO4 | c.982T>C p.L328= | Silent (SNP) | VAF 118/767 reads (15%) | called by muse, mutect2, varscan2
- FGF20 | c.534C>T p.G178= | Silent (SNP) | VAF 48/662 reads (7%) | catalogued as rs373023438; called by muse, mutect2
- FKBPL | c.183G>A p.E61= | Silent (SNP) | VAF 89/198 reads (45%) | called by muse, mutect2, varscan2
- LEMD3 | c.1839C>G p.S613= | Silent (SNP) | VAF 185/938 reads (20%) | called by muse, mutect2, varscan2
- MRGPRE | c.786C>T p.C262= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as rs576704362; called by muse, mutect2, varscan2
- MUC5B | c.270C>T p.G90= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as rs377569377; called by muse, mutect2, varscan2
- SASS6 | c.948C>T p.H316= | Silent (SNP) | VAF 268/1151 reads (23%) | catalogued as rs758597069; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 29/1228 reads (2%) | called by muse, mutect2
- CDNF | c.-21G>C | 5'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- LDHD | c.328-73C>T | Intron (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- NDNF | c.*92G>A | 3'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- NFKBIA | c.337-54G>T | Intron (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
